FM case AD13067 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/0d73a54d-0726-41a3-bd36-51c8dfe29c07

Female, 38.7 years: Adenocarcinoma, diffuse type (ICD-O-3 8145/3) of the stomach; metastasis biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
